Somatic mutation profile of tumor specimen MMRF_1024_2_BM_CD138pos (aliquot MMRF_1024_2_BM_CD138pos_T2_KHS5U_L13428) from MMRF case MMRF_1024, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.0 years (29,222 days).
Specimen MMRF_1024_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1989aeb6-43f6-4c5c-9d28-1fc4c786040b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1024_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1024_2_PB_Whole_C1_KHS5U_L13427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2102bbbe-537c-4d1d-8976-e497262ad542

The open-access MAF lists 97 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 21, Intron 18, Silent 11, 5'UTR 5, 3'Flank 5, 5'Flank 3, RNA 3, In Frame Del 2, Nonsense Mutation 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs955802520, COSV99227484; called by muse, mutect2, varscan2
- BTD | c.1076A>C p.H359P | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs763540316; called by muse, mutect2, varscan2
- CSMD1 | c.5636C>T p.P1879L (on ENST00000520002; = p.P1878L on NM_033225.6) | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs541928934, COSV59340940; called by muse, mutect2, varscan2
- IGHV1-24 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 188/436 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs374770361; called by muse, mutect2, varscan2
- IL18RAP | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV51825778; called by muse, mutect2, varscan2
- KLK1 | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 180/576 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV56827336; called by muse, mutect2
- KLK3 | c.630+6T>C | Splice Region (SNP) | VAF 31/98 reads (32%) | catalogued as rs767017605; called by muse, mutect2, varscan2
- LCT | c.4363C>T p.R1455C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763006562, COSV51554202; called by muse, mutect2, varscan2
- NRG3 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as rs771942584, COSV64541957; called by muse, mutect2, varscan2
- OBSCN | c.14239C>T p.R4747C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481359710, COSV52759187; called by muse, mutect2, varscan2
- PEPD | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781520198; called by muse, mutect2, varscan2
- RTL1 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1566753444; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1086T>G p.D362E | Missense Mutation (SNP) | VAF 129/314 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ADRM1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BAHCC1 | c.4818C>G p.I1606M | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by muse, varscan2
- BFSP1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- C10orf67 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.98); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C5orf47 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLINT1 | c.1266_1274del p.F424_L426del | In Frame Del (DEL) | VAF 21/146 reads (14%) | called by mutect2, pindel, varscan2
- EPHX1 | c.979_981del p.E327del | In Frame Del (DEL) | VAF 95/487 reads (20%) | called by mutect2, pindel, varscan2
- FBXL17 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GTF2E1 | c.750C>A p.Y250* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- H2BC6 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- IGKV1-6 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, varscan2
- RNH1 | c.58T>G p.W20G | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SDK2 | c.3773C>T p.S1258F | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SDK2 | c.3691C>T p.L1231F | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, varscan2
- SEMA4C | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SNRNP200 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX47 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 193/431 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ZNF253 | c.853A>G p.K285E | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- BAHCC1 | c.4635C>T p.V1545= | Silent (SNP) | VAF 72/171 reads (42%) | called by muse, varscan2
- BAHCC1 | c.5328C>G p.L1776= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- BAHCC1 | c.5370C>T p.S1790= | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, varscan2
- BIRC6 | c.5982C>T p.L1994= | Silent (SNP) | VAF 42/126 reads (33%) | called by muse, mutect2, varscan2
- CAND1 | c.3132A>G p.L1044= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs780390167; called by muse, mutect2, varscan2
- DENND2C | c.535A>C p.R179= | Silent (SNP) | VAF 69/163 reads (42%) | called by muse, mutect2, varscan2
- GSTT4 | c.510C>T p.A170= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs1308750931; called by muse, mutect2, varscan2
- HAUS3 | c.507T>C p.L169= | Silent (SNP) | VAF 56/97 reads (58%) | called by muse, mutect2, varscan2
- KLF11 | c.675C>T p.S225= | Silent (SNP) | VAF 72/170 reads (42%) | called by muse, mutect2, varscan2
- MLST8 | c.486C>T p.N162= | Silent (SNP) | VAF 104/300 reads (35%) | catalogued as rs185180342, COSV57030914; called by muse, mutect2, varscan2
- USP31 | c.1359C>T p.S453= | Silent (SNP) | VAF 67/132 reads (51%) | catalogued as rs1406198248; called by muse, mutect2, varscan2
- ABHD17B | c.*1427G>A | 3'UTR (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- AC002511.3 | n.324+19G>C | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- AC012560.1 | n.570G>T | RNA (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+8641G>T | Intron (SNP) | VAF 29/146 reads (20%) | called by muse, mutect2, varscan2
- ACTN4 | c.*482C>G | 3'UTR (SNP) | VAF 168/265 reads (63%) | called by muse, mutect2, varscan2
- AFAP1 | c.*446G>T | 3'UTR (SNP) | VAF 42/176 reads (24%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824703 C>T | 5'Flank (SNP) | VAF 19/25 reads (76%) | catalogued as rs1416918152; called by muse, mutect2, varscan2
- ARF1 | c.*210C>T | 3'UTR (SNP) | VAF 15/71 reads (21%) | catalogued as rs1431469626; called by muse, mutect2, varscan2
- ASCL2 | c.-569C>T | 5'UTR (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- ATRNL1 | c.620+67del | Intron (DEL) | VAF 5/14 reads (36%) | catalogued as rs1294683099; called by mutect2, varscan2
- CADPS | c.1325+20443T>C | Intron (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2
- CCSER1 | c.*708T>G | 3'UTR (SNP) | VAF 42/100 reads (42%) | called by muse, mutect2, varscan2
- COL1A1 | c.*891C>A | 3'UTR (SNP) | VAF 36/228 reads (16%) | called by muse, mutect2, varscan2
- COLQ | chr3:15521743 del GTGC | 5'Flank (DEL) | VAF 3/25 reads (12%) | catalogued as rs886058111; ClinVar: uncertain significance; called by pindel, varscan2*
- DAOA | c.*111+48A>T | Intron (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
- DYNLL1 | c.-6-33A>G | Intron (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- EDARADD | c.61+1027A>T | Intron (SNP) | VAF 28/121 reads (23%) | catalogued as rs1034918114; called by muse, mutect2, varscan2
- EPHA5 | c.*3694T>G | 3'UTR (SNP) | VAF 58/152 reads (38%) | called by muse, mutect2, varscan2
- FAM178B | c.*378G>A | 3'UTR (SNP) | VAF 60/180 reads (33%) | called by muse, mutect2, varscan2
- FOXN1 | c.*88G>A | 3'UTR (SNP) | VAF 68/164 reads (41%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+19607A>C | Intron (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- GORASP2 | c.63+422T>C | Intron (SNP) | VAF 20/46 reads (43%) | called by mutect2, varscan2
- HOXB3 | chr17:48545286 C>A | 3'Flank (SNP) | VAF 127/269 reads (47%) | called by muse, mutect2, varscan2
- HSPA1B | chr6:31834956 T>C | 3'Flank (SNP) | VAF 42/74 reads (57%) | catalogued as rs556207281; called by muse, mutect2, varscan2
- KLRG1 | c.83-78C>T | Intron (SNP) | VAF 79/201 reads (39%) | catalogued as rs764439397, COSV56944360; called by muse, mutect2, varscan2
- KTN1 | c.*90T>C | 3'UTR (SNP) | VAF 237/609 reads (39%) | called by muse, mutect2, varscan2
- LINC01565 | n.453G>A | RNA (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- LINS1 | c.*1846T>C | 3'UTR (SNP) | VAF 33/167 reads (20%) | called by muse, mutect2, varscan2
- LPAR3 | c.*1103T>A | 3'UTR (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- LTN1 | c.2163+1192T>C | Intron (SNP) | VAF 75/198 reads (38%) | called by muse, mutect2, varscan2
- LUZP2 | c.-52G>A | 5'UTR (SNP) | VAF 156/260 reads (60%) | called by mutect2, varscan2
- MTR | c.*3768C>A | 3'UTR (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- NME1 | chr17:51162349 C>A | 3'Flank (SNP) | VAF 11/70 reads (16%) | called by muse, varscan2
- PAX7 | c.*646G>A | 3'UTR (SNP) | VAF 55/132 reads (42%) | catalogued as rs1330849323; called by muse, mutect2, varscan2
- PCSK5 | c.*60G>A | 3'UTR (SNP) | VAF 220/698 reads (32%) | called by muse, mutect2, varscan2
- PHF21B | c.*1394C>T | 3'UTR (SNP) | VAF 46/108 reads (43%) | catalogued as rs994237857; called by muse, mutect2, varscan2
- PLEKHA5 | c.2400+1226C>T | Intron (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- PPP3R1 | chr2:68253058 G>A | 5'Flank (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- PTPN22 | c.88-4764C>T | Intron (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- QPRT | c.*663G>A | 3'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- RAB43P1 | n.182G>A | RNA (SNP) | VAF 5/94 reads (5%) | catalogued as rs979911401; called by muse, mutect2
- RARB | c.-5G>A | 5'UTR (SNP) | VAF 95/247 reads (38%) | catalogued as rs549712167; called by muse, mutect2, varscan2
- RBM11 | c.*569A>G | 3'UTR (SNP) | VAF 16/50 reads (32%) | catalogued as rs1002358880; called by muse, mutect2, varscan2
- RBM8A | c.206-70A>G | Intron (SNP) | VAF 36/56 reads (64%) | called by muse, mutect2, varscan2
- RIN1 | c.547+73_547+74insA | Intron (INS) | VAF 32/98 reads (33%) | called by mutect2, pindel*, varscan2
- S1PR3 | c.-148+2172A>C | Intron (SNP) | VAF 26/177 reads (15%) | called by muse, mutect2, varscan2
- SET | c.113-1605del | Intron (DEL) | VAF 5/41 reads (12%) | catalogued as rs757604683; called by mutect2, varscan2
- SLC9A1 | c.-606G>T | 5'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145829302 C>T | 3'Flank (SNP) | VAF 25/57 reads (44%) | catalogued as rs1556946395; called by muse, mutect2, varscan2
- STRN3 | c.*305G>A | 3'UTR (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2
- TM2D1 | c.514-75_514-73del | Intron (DEL) | VAF 26/63 reads (41%) | called by pindel, varscan2
- TMSB4X | c.-58C>T | 5'UTR (SNP) | VAF 73/89 reads (82%) | called by muse, mutect2, varscan2
- TYW3 | c.*939A>G | 3'UTR (SNP) | VAF 6/139 reads (4%) | called by muse, mutect2
- U2SURP | c.*720A>G | 3'UTR (SNP) | VAF 52/116 reads (45%) | catalogued as rs1023108424; called by muse, mutect2, varscan2
- VN2R19P | chr19:58011024 del TT | 3'Flank (DEL) | VAF 61/261 reads (23%) | called by mutect2, pindel, varscan2
